Gene-level copy-number profile of tumor specimen TCGA-55-1594-01A from TCGA case TCGA-55-1594, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.5 years (25,008 days).
Specimen TCGA-55-1594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3567dec1-b49e-4903-81f3-efe9acfdf76c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-1594-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6161088-96ec-4796-99e0-81eecaedb15e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 208; copy number 2: 18,700; copy number 3: 16,686; copy number 4: 15,449; copy number 5: 7,155; copy number 6: 485; copy number 7: 204; copy number 8: 360; copy number 9: 110; copy number 10: 5; copy number 11: 153; copy number 13: 51; copy number 17: 119; copy number 19: 19; copy number 23: 72; copy number 33: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-1594-01A-01D-0944-01): tumor purity 0.55, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,136 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:57,720,035–61,153,962, 23 genes, copy number 9: AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271.
- chr4:61,211,652–61,428,221, 2 genes, copy number 9: RPL17P19, AC020741.1.
- chr4:65,142,703–66,150,012, 10 genes, copy number 9 (within-gene range 6–9): EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1.
- chr4:66,094,142–66,431,521, 4 genes, copy number 9: IFITM3P1, AC110809.1, MIR1269A, RPS23P3.
- chr4:67,701,209–68,080,952, 1 gene, copy number 8 (within-gene range 5–8): UBA6-AS1.
- chr4:67,820,876–78,008,688, 227 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:5,972,412–8,760,447, 51 genes, copy number 8: PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3.
- chr6:8,653,558–8,653,797, 1 gene, copy number 8: AL161437.1.
- chr7:49,760,897–64,950,701, 321 genes, copy number 7–11 (broad region; genes not listed).
- chr14:33,924,227–34,486,447, 5 genes, copy number 10: EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71.
- chr14:35,430,260–40,390,547, 82 genes, copy number 9–33 (within-gene range 3–33) (broad region; genes not listed).
- chr14:41,514,972–53,157,528, 191 genes, copy number 17–23 (broad region; genes not listed).
- chr16:50,664,903–53,329,150, 51 genes, copy number 13 (within-gene range 4–13): AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1, HNRNPA1P48, RN7SKP142, LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1, PHBP21, AC007346.1, AC007346.2, AC007906.2, CHD9, AC007906.1, AC079416.4.
- chr20:46,168,404–47,412,327, 29 genes, copy number 7: AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754.
- chr20:49,503,874–55,075,140, 96 genes, copy number 8–9 (broad region; genes not listed).
- chr20:58,817,132–60,653,784, 42 genes, copy number 7–8: AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2.

Autosomal genes at a single copy (total copy number 1): 201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
